Gene-level copy-number profile of tumor specimen TCGA-RC-A6M4-01A from TCGA case TCGA-RC-A6M4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,327 days).
Specimen TCGA-RC-A6M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c21956a3-7548-4077-a56b-e6ed91f1f846.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RC-A6M4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/245b3ad6-240e-4999-8704-462677914783

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,352; copy number 3: 15,654; copy number 4: 33,988; copy number 5: 141; copy number 6: 3,039; copy number 7: 719; copy number 8: 71; copy number 9: 776; copy number 10: 70; copy number 11: 5; copy number 12: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RC-A6M4-01A-11D-A32F-01): tumor purity 0.86, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 842 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,508,559–221,742,089, 5 genes, copy number 11 (within-gene range 6–11): AL360013.2, AL360013.3, AL360013.1, AL360013.4, DUSP10.
- chr7:38,256,337–38,330,935, 13 genes, copy number 10: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr7:152,402,780–152,757,951, 11 genes, copy number 9: Y_RNA, FABP5P3, CCT8L1P, LINC01003, AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P.
- chr8:97,775,057–97,853,013, 1 gene, copy number 9 (within-gene range 7–9): LAPTM4B.
- chr8:97,853,021–145,066,685, 755 genes, copy number 9–12 (broad region; genes not listed).
- chr14:22,147,995–22,506,702, 57 genes, copy number 10: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
